Somatic mutation profile of tumor specimen TCGA-FF-8046-01A (aliquot TCGA-FF-8046-01A-11D-2210-10) from TCGA case TCGA-FF-8046, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Submandibular gland; Age at diagnosis: 51.6 years (18,853 days).
Specimen TCGA-FF-8046-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31a2da60-a646-4ef7-bc93-1ed8ccb9671d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-8046-10A (Blood Derived Normal), aliquot TCGA-FF-8046-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dbffb46-df4e-4bf0-b393-cd10f167e427

The open-access MAF lists 76 somatic variants for this specimen: 49 protein-altering or splice-affecting, 17 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 17, Intron 5, Nonsense Mutation 3, 3'UTR 2, RNA 2, Splice Site 2, Frame Shift Ins 2, Splice Region 2, 5'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKBKB | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1563340753, COSV60596575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYC | c.733C>G p.P245A (on ENST00000377970; = p.P260A on NM_002467.6) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.454); catalogued as rs1057519851, COSV52381674, COSV99418971; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV101434980; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1489C>G p.R497G | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV63244587; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 29/127 reads (23%) | catalogued as rs372345940; called by mutect2, varscan2
- CHIT1 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs749457823, COSV55146459; called by muse, mutect2, varscan2
- CNTNAP2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV62251654; called by muse, mutect2, varscan2
- COL22A1 | c.3978G>A p.P1326= | Splice Region (SNP) | VAF 34/136 reads (25%) | catalogued as rs139816222; called by muse, mutect2, varscan2
- CSPG4 | c.3136G>A p.D1046N | Missense Mutation (SNP) | VAF 95/186 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552897521; called by muse, mutect2, varscan2
- DDX3X | c.1312+1G>T p.X438_splice (on ENST00000399959; = p.X439_splice on NM_001356.5) | Splice Site (SNP) | VAF 65/121 reads (54%) | catalogued as COSV101302345; called by muse, mutect2, varscan2
- FRMD3 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs770065695; called by muse, mutect2, varscan2
- GPR101 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs751971846, COSV53237468; called by muse, mutect2, varscan2
- GRM4 | c.1737C>G p.I579M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as rs778302214; called by muse, mutect2, varscan2
- HLA-B | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs281864589, COSV69520839; called by muse, mutect2
- IGLV2-14 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.722); catalogued as rs756145440; called by muse, mutect2, varscan2
- IGLV3-16 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs752247264; called by muse, varscan2
- IGLV3-25 | c.147A>T p.Q49H | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1428731805; called by muse, varscan2
- LGI3 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748983195, COSV100103224; called by muse, mutect2, varscan2
- LPIN3 | c.335dup p.L113Sfs*15 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs756955559; called by mutect2, varscan2
- LRIG1 | c.2566G>C p.V856L | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs147267806; called by muse, mutect2, varscan2
- LRP1B | c.7514-1G>T p.X2505_splice | Splice Site (SNP) | VAF 26/79 reads (33%) | catalogued as rs1284978290, COSV101252993; called by muse, mutect2, varscan2
- MYC | c.918G>C p.Q306H (on ENST00000377970; = p.Q321H on NM_002467.6) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52375220, COSV52375789; called by muse, varscan2
- RFX7 | c.1771C>T p.Q591* (on ENST00000559447 / NM_001368074.1; = p.Q688* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 119/294 reads (40%) | catalogued as COSV100428270; called by muse, mutect2, varscan2
- SRSF7 | c.49A>T p.N17Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57447535; called by muse, mutect2, varscan2
- SVEP1 | c.1800G>C p.K600N | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs1564159382, COSV57030621; called by muse, mutect2, varscan2
- TACC1 | c.791A>G p.Y264C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs777213190; called by muse, varscan2
- TMEM30A | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 49/131 reads (37%) | catalogued as rs772644735, COSV57874607; called by muse, mutect2, varscan2
- ZNF233 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs569951523, COSV100492505; called by muse, mutect2, varscan2
- ABCA8 | c.1500A>G p.K500= | Splice Region (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- ALDOB | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CEP41 | c.93C>A p.D31E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CHST4 | c.65del p.L22Hfs*15 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- GRB2 | c.298A>G p.K100E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.295); called by muse, mutect2
- HLA-B | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ID3 | c.228C>A p.Y76* | Nonsense Mutation (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.189_197del p.L64_I66del | In Frame Del (DEL) | VAF 22/132 reads (17%) | called by pindel, varscan2
- ITGA10 | c.335T>A p.L112Q | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR1 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MACROD2 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAP1L3 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.166); called by muse, varscan2
- ODR4 | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PDE3A | c.1956A>T p.K652N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- SPAG5 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SRSF7 | c.318C>G p.C106W | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYDE1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPO | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZMYND15 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF33A | c.290A>C p.N97T (on ENST00000458705 / NM_006974.3; = p.N98T on NM_006954.2) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ZNF438 | c.1699A>C p.M567L | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARRDC4 | c.876C>G p.S292= | Silent (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- DOCK3 | c.2877T>C p.H959= | Silent (SNP) | VAF 55/204 reads (27%) | called by muse, mutect2, varscan2
- FKBP9 | c.471G>A p.P157= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs1268268379, COSV54229966; called by muse, mutect2, varscan2
- H2AC6 | c.228G>A p.K76= | Silent (SNP) | VAF 55/236 reads (23%) | catalogued as COSV58416554; called by muse, mutect2, varscan2
- IGKV1-33 | c.198T>A p.P66= | Silent (SNP) | VAF 39/217 reads (18%) | catalogued as rs1449210655, COSV101522084; called by muse, mutect2, varscan2
- IGLV3-16 | c.336T>C p.S112= | Silent (SNP) | VAF 25/55 reads (45%) | called by muse, varscan2
- KRTAP26-1 | c.72C>A p.L24= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as COSV100860441, COSV62128422; called by muse, mutect2, varscan2
- MITF | c.138G>A p.P46= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs199697494; called by muse, mutect2, varscan2
- MYC | c.295C>T p.L99= (on ENST00000377970; = p.L114= on NM_002467.6) | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV52380433, COSV99420109; called by muse, mutect2, varscan2
- MYC | c.513C>T p.C171= (on ENST00000377970; = p.C186= on NM_002467.6) | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- MYC | c.1023A>G p.K341= (on ENST00000377970; = p.K356= on NM_002467.6) | Silent (SNP) | VAF 49/127 reads (39%) | called by muse, varscan2
- NDUFS3 | c.114C>T p.S38= | Silent (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- NEB | c.11904G>T p.V3968= | Silent (SNP) | VAF 49/146 reads (34%) | called by muse, mutect2, varscan2
- SEC14L3 | c.51C>G p.A17= | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- SMC1B | c.517A>C p.R173= | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- TPTE | c.51C>T p.L17= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs768325326; called by muse, mutect2, varscan2
- ZBTB7C | c.681C>T p.I227= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as rs747113694, COSV59690998; called by muse, mutect2, varscan2
- ANKRD23 | c.-21G>C | 5'UTR (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100450331; called by muse, mutect2, varscan2
- ARHGEF11 | c.583-1661G>T | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- BTNL10 | n.176del | RNA (DEL) | VAF 31/140 reads (22%) | called by mutect2, pindel, varscan2
- DLG2 | c.205-65622G>A | Intron (SNP) | VAF 22/67 reads (33%) | catalogued as rs569088235, COSV54625010; called by muse, mutect2, varscan2
- KIF21A | c.1469+9C>A | Intron (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- LRRC8D | c.*206T>A | 3'UTR (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100487039; called by muse, mutect2, varscan2
- MIR1204 | n.16C>T | RNA (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-650G>T | Intron (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- RPL10 | c.24-396A>T | Intron (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- TPD52L3 | c.*734T>A | 3'UTR (SNP) | VAF 59/192 reads (31%) | catalogued as COSV100095869; called by muse, mutect2, varscan2
